Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABLE, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABLE-TTP1-B (Primary Tumor).

[page 1 of 2]
CDDP-YP-ABLE-01-PR

Previous exams

Previous exams exist.

Clinical Data and Diagnostic Questions

Patient with pulmonary left neoformation

Material description

1. Upper lobe, left lung / surgical sample
2. Lymph node n.10/ surgical biopsy
3. Lymph node n. 5/ surgical biopsy
4. Lymph node n.10/ surgical biopsy
5. Lymph node n.11/ surgical biopsy
6. Lymph node n.11/ surgical biopsy
7. Lymph node n.12/ surgical biopsy
8. Lymph node n. 10/ surgical biopsy
9. Bronchus at level section / surgical biopsy
10. Lymph node n. 2/ surgical biopsy
11. Mediastinal tissue / surgical biopsy

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: (L) lung, upper lobe C34.1

ICD-10

C34.12

hw
2/12/16

Macro description

1. Pulmonary lobe 20 x 10 x 4 cm. When you cut, in apical place, it is a nodular lesion of 2 x 2 x 1.5 cm made up of tissue of increased compactness, with blackish stripes. The lesion retracts the above visceral pleura. The remaining parenchyma is soft. Bronchus of section and hilar structures negative.
2. Brownish fragment with bigger axis of 4 mm
3. Fragment of lymph node parenchyma anthracotic with bigger axis of 9 mm
4. Fragment of anthracotic lymph node with bigger axis of 5 mm
5. Brownish fragment with bigger axis of 11 mm
6. Two fragments with bigger axis of 3 mm
7. Anthracotic lymph node with bigger axis of 11 mm
8. Brownish fragment with bigger axis of 7 mm
9. Fragment of cartilaginous bronchus with bigger axis of 3 mm
10. Anthracotic lymph node with bigger axis of 11 mm
11. Fibroadipose fragment of 5 x 3 x 1.5 cm containing, when you cut, some lymph nodes, biggest of 1,2 cm

[page 2 of 2]
Micro description

1. Confirming what verbally expressed during the extemporaneous examination, the histological definitive sections after fixation and inclusion, the successive samples show pulmonary parenchyma place of moderately differentiated adenocarcinoma. The neoplasm is made up of tubules, glands, nests, aggregates of elements with wide, eosinophil cytoplasm, vesicular and irregular nucleus, markedly pleomorphic.

The neoplasm is surrounded by a sclero-anthratic and elastotic stroma. The neoplasm comes close to the above visceral pleura. No evidence of sure invasions intratumoural and/or peritumoural.

The pulmonary, not neoplastic, parenchyma presents bronchiolitis of respiratory type. Bronchus of section negative for neoplasm.

2. A fragment of adipose tissue negative for neoplastic infiltration. No evidence of lymph node parenchyma.

3.4. The lymph nodes n. 5 and n. 10 are place of metastasis of adenocarcinoma with the morphological characters as described under 1.

5.6.7.8. The lymph nodes n.11, n.12, and n.10 are anthracotic and negative for neoplasm

9. Histological sections of fragment di hyaline cartilage in the morphologic variability of the standard, separated by thin band of fibrous tissue. No evidence of neoplastic infiltration.

10. The biopsy sample is made up of fragment of fibroadipose tissue negative for neoplastic infiltration

11. The performed samples show fragment of fibroadipose tissue characterized by infiltration of adenocarcinoma with the morphological characters as described under 1.

We detect discrete neurotropism.

Conclusions and histopathological diagnosis

1. Moderately differentiated adenocarcinoma, infiltrating the pulmonary parenchyma.

2.9.10. Negative for neoplasm

3.4. Lymph node metastasis of adenocarcinoma

5.6.7.8. Lymph node anthracosis

11. Infiltration of adenocarcinoma

Staging pTNM: MISSING

Source: NCI Genomic Data Commons file c3813f2a-746a-4231-8e4b-f55e4b021852 (CDDP-ABLE-TTP1.CBEA8FE6-4BBC-41AD-834C-C0660186AC6E.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).